Somatic mutation profile of tumor specimen 0DKAKW from CCDI case PBBXVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 16.5 years (6,028 days).
Specimen 0DKAKW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f71c7557-d1e1-44bc-b502-e402dd3b9337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKAKL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a6f5238-75de-4dfa-b374-cb240f87ee19

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 221/556 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- C2orf50 | c.429C>A p.D143E | Missense Mutation (SNP) | VAF 150/449 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs919569585; called by muse, varscan2
- FRMD1 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99350024; called by muse, mutect2, varscan2
- ONECUT2 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 57/509 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755413489, COSV72153285; called by muse, mutect2, varscan2
- CEBPB | c.817_822del p.E273_Y274del | In Frame Del (DEL) | VAF 56/319 reads (18%) | called by mutect2, varscan2
- TTN | c.17113G>T p.D5705Y (on ENST00000591111; = p.D4778Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 325/767 reads (42%) | PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- EHMT2 | c.3006G>A p.L1002= | Silent (SNP) | VAF 203/482 reads (42%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.3532+14A>T | Intron (SNP) | VAF 274/656 reads (42%) | called by mutect2, varscan2
